Surgical pathology report (de-identified scan), TCGA case TCGA-56-8629, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8629-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

DIAGNOSIS:

A. Subcarinal lymph node, excision:
Malignancy not identified.

B. Level 9 lymph node, excision:
Anthracosis.
Malignancy not identified.

C. Level 7 lymph node, excision:
Anthracosis.
Malignancy not identified.

D. Lung, left lower lobe, excision:

Tumor Characteristics:

1. Histologic type: Squamous cell carcinoma.
2. Histologic grade: Grade 2, moderately differentiated.
3. Tumor site: Left lower lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 6.0 x 5.5 x 5.0 cm.
6. Visceral pleural invasion: Not identified.
7. Lymphovascular space invasion: Not identified.
8. Tumor extension: Tumor confined to lung parenchyma.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 1.0 cm.
2. Tumor distance from pleural surface: Tumor focally in contact with pleural surface but does not extend through.

Lymph Node Status:

1. Three peribronchial lymph nodes present, negative for metastatic disease.

Other:

1. Frozen section diagnosis confirmed.
2. pTNM stage: pT2b N0.

E. Level 6 lymph node, excision:

Anthracosis without evidence of metastatic disease.

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] left lower lobe lung carcinoma, squamous cell carcinoma
Postoperative Diagnosis: [REDACTED]
Symptoms/Radiologic Findings:

CLINICAL INFORMATION**SPECIMENS:**

- A. Subcarinal lymph node
- B. Level 9 lymph node
- C. Level 7 lymph node
- D. Left lower lobe, frozen section on bronchial margins with frozen section
- E. Level 6 lymph node

GROSS DESCRIPTION:

The specimen is received in five containers labeled with the patient's name

SPECIMEN DATA

- A. Container A is additionally labeled 'subcarinal lymph node' and contains a 2.0 cm tan-gray rubbery nodule consistent with possible lymph node. The nodule is trisected and entirely submitted in cassette A1 labeled [REDACTED]
- B. Container B is additionally labeled 'level 9 lymph node' and contains a 2.0 x 1.1 x 0.6 cm tan-brown fibrofatty nodule consistent with lymph node. The nodule is bisected and entirely submitted in cassette B1 labeled [REDACTED]
- C. Container C is additionally labeled 'level 7 lymph node' and contains a 2.4 x 1.3 x 0.9 cm tan-brown, rubbery nodule consistent with anthracotic lymph node. The specimen is bisected and entirely submitted in cassette C1 labeled [REDACTED]
- D. Container D is additionally labeled 'left lower lobe' and contains a 15.0 x 13.0 x 8.5 cm lung lobe bearing a 0.5 cm in length x 1.3 cm in diameter segment of exposed bronchus. Adjacent to the bronchus are segments of stapled vasculature. No tumor is identified at the stapled bronchial or vascular margins. The pleura is purple-gray, moderately anthracotic. On sectioning, a 6.0 x 5.5 x 5.0 cm ill-defined gray-white centrally cystic mass is present. This mass approaches to within 1.0 cm of the bronchial and vascular margins and abuts the inked pleura adjacent to the bronchi and vasculature. The remainder of the cut surface is comprised of beefy red spongy parenchyma with no additional lesions identified. Three possible parabronchial lymph nodes are identified up to 1.0 cm in greatest dimension. The bronchial margin is submitted en face for frozen section. The residual is entirely resubmitted for permanent section cassette D1 labeled [REDACTED]. Additional representative sections are submitted in cassettes D2 through 12 designated as follows: D2, vascular margins, en face; D3 and 4, mass to bronchus, one parabronchial lymph node in cassette D4; cassettes D5 and 6, mass to exposed vasculature; D7 and 8, mass to inked pleura, perpendicular; D9, mass to normal appearing parenchyma; D10, additional mass; D11, one whole possible bisected parabronchial lymph node; D12, one whole possible parabronchial lymph node. Additionally, a yellow, green and blue cassette are submitted for genomics research, each labeled [REDACTED]
- E. Container E is additionally labeled 'level 6 lymph node' and contains a 1.5 cm yellow-black rubbery nodule consistent with anthracotic lymph node. The nodule is bisected and entirely submitted in cassette E1 labeled [REDACTED]

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS: Part D. Tumor not identified per Dr. [REDACTED]

Source: NCI Genomic Data Commons file bd933d6d-e657-4760-9007-2c59112df1cd (TCGA-56-8629.673BCFF6-EF66-481F-BABA-50C86F18D551.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).